Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040037-09A.2 (aliquot TARGET-15-SJMPAL040037-09A.2-01D) from TARGET case TARGET-15-SJMPAL040037, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,594 days).
Specimen TARGET-15-SJMPAL040037-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc9ff582-579c-4392-b196-d2985e823c6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040037-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040037-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70780a70-1afa-474a-83dc-a92f59062725

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, 3'UTR 2, Frame Shift Ins 2, Intron 1, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA8 | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51263500; called by muse, mutect2
- NRXN1 | c.1310G>T p.C437F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58452271; called by muse, mutect2
- OSGIN1 | n.1028+1G>A | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as rs768497100; called by muse, mutect2, varscan2
- SSC5D | c.3854C>T p.T1285M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs201172616; called by muse, varscan2
- TBX3 | c.1196C>T p.T399M (on ENST00000257566 / NM_016569.4; = p.T379M on NM_005996.4) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs746953122; called by muse, mutect2, varscan2
- WT1 | c.1189delinsAGATCA p.Q397Rfs*42 | Frame Shift Ins (INS) | VAF 28/79 reads (35%) | catalogued as CM041869, COSV60066810, COSV60071867; called by pindel, varscan2*
- WT1 | c.1102_1103insTGGGGCG p.R368Lfs*7 | Frame Shift Ins (INS) | VAF 32/106 reads (30%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by pindel, varscan2
- BCL9 | c.825C>A p.D275E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.049); called by muse, mutect2
- CAMTA1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX17 | c.795T>A p.D265E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EGR3 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRF5 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGB7 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- MACF1 | c.12452C>A p.A4151D (on ENST00000372915; = p.A2084D on NM_012090.5) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- MUC21 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 117/276 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARP9 | c.1878G>T p.W626C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.293); called by muse, mutect2
- PRX | c.35G>T p.R12M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- SIM2 | c.1173C>A p.Y391* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- ZNF641 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDCA4 | c.270G>T p.A90= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- RIN2 | c.2173C>A p.R725= (on ENST00000255006 / NM_001242581.1; = p.R676= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- ZNF184 | c.327G>T p.V109= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- ARHGEF4 | c.428-16116G>A | Intron (SNP) | VAF 69/163 reads (42%) | called by muse, mutect2, varscan2
- EXOC3L1 | c.*6G>T | 3'UTR (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- FAM205BP | n.821G>A | RNA (SNP) | VAF 9/99 reads (9%) | catalogued as rs369553984; called by muse, mutect2
- OGG1 | c.*7G>A | 3'UTR (SNP) | VAF 67/129 reads (52%) | called by muse, mutect2, varscan2
